MMRF case MMRF_2056 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f5ab2d5f-a52b-4dd0-b75f-b23171ac5a66

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.7 years (18,506 days); ISS stage: I; Days to last known disease status: 918 days (2.5 years); Days to last follow up: 918 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 142 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 144 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 359 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 359 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 5.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.128 mg/dL; Immunoglobulin G 73.6 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 12 g/dL; Glucose 6.77 mmol/L; C-Reactive Protein 0.3 mg/dL.
- Day 85 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.239 mg/dL; Immunoglobulin G 9.52 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 331 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 176 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.114 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.66 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 267 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.179 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.548 mg/dL; Immunoglobulin G 4.58 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.77 ×10⁹/L; Platelets 319 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 6.55 mmol/L.
- Day 358 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.715 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 4.07 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.93 ×10⁹/L; Platelets 473 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 7.87 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.207 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.87 mg/dL; Immunoglobulin G 5.32 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.66 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 6.49 mmol/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.146 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 260 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 13.1 mmol/L.
- Day 638 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.959 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.29 mg/dL; Immunoglobulin G 2.7 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 329 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 7.32 mmol/L.
- Day 730 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0302 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.116 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 4.52 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.26 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 9.63 mmol/L.
- Day 806 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0325 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.143 mg/dL; Immunoglobulin G 2.36 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.24 ×10⁹/L; Platelets 249 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.7 g/dL; Glucose 12.7 mmol/L.
- Day 918 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.032 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.0384 mg/dL; Immunoglobulin G 2.49 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 11 mmol/L.

Other clinical attributes
- Day -4: Weight: 62 kg; Height: 168 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2056_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2056_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
